Gene-level copy-number profile of tumor specimen ALCH-B1RY-TTP1-A from ALCHEMIST case ALCH-B1RY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.5 years (21,736 days).
Specimen ALCH-B1RY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e89886f6-cb4b-4f31-af17-5a3fc06e6008.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1RY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/aed108a6-c248-4482-8602-01299c80f6c2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 115; copy number 2: 51,142; copy number 3: 7,105; copy number 4: 17; copy number 5: 8; copy number 6: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,548,756–248,565,299, 3 genes, copy number 6: AC098483.1, OR2AS1P, OR2T29.
- chr15:28,519,611–28,533,014, 2 genes, copy number 5: GOLGA8G, Metazoa_SRP.
- chr20:26,103,416–26,251,546, 6 genes, copy number 5: NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A.

Autosomal genes at a single copy (total copy number 1): 115. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
